Somatic mutation profile of tumor specimen TCGA-13-0905-01B (aliquot TCGA-13-0905-01B-01W-0492-08) from TCGA case TCGA-13-0905, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 51.4 years (18,757 days).
Specimen TCGA-13-0905-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) daa07075-605b-42e3-a4fd-afc4aa0efc9a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-13-0905-10A (Blood Derived Normal), aliquot TCGA-13-0905-10A-01W-0492-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c881f065-c062-47dc-aeb4-1ffa8ac6dd13

The open-access MAF lists 91 somatic variants for this specimen: 68 protein-altering or splice-affecting, 22 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 57, Silent 22, Nonsense Mutation 3, Frame Shift Del 2, In Frame Del 2, Splice Site 2, Splice Region 1, Frame Shift Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.818G>C p.R273P | Missense Mutation (SNP) | VAF 49/55 reads (89%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCG1 | c.638G>A p.R213Q | Missense Mutation (SNP) | VAF 67/133 reads (50%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.883); catalogued as rs772470306, COSV59202048; called by muse, mutect2, varscan2
- ADA2 | c.581A>C p.E194A | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.408); catalogued as COSV52830746; called by muse, mutect2, varscan2
- ADNP2 | c.940G>C p.G314R | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.369); catalogued as rs1568415406, COSV100081146; called by muse, mutect2
- AZIN2 | c.224C>G p.P75R | Missense Mutation (SNP) | VAF 129/285 reads (45%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as COSV53856513; called by muse, mutect2, varscan2
- B3GAT3 | c.486C>G p.N162K | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53881753; called by muse, mutect2, varscan2
- C6orf47 | c.464T>A p.L155* | Nonsense Mutation (SNP) | VAF 105/114 reads (92%) | catalogued as COSV63263668; called by muse, mutect2, varscan2
- CAMK4 | c.829-2A>C p.X277_splice | Splice Site (SNP) | VAF 6/118 reads (5%) | catalogued as COSV100000114; called by muse, mutect2
- CC2D1B | c.1600C>T p.R534W | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); catalogued as rs756850623, COSV52559133; called by muse, mutect2, varscan2
- CERKL | c.1511G>C p.G504A (on ENST00000339098 / NM_001030311.2; = p.G478A on NM_201548.5) | Missense Mutation (SNP) | VAF 20/430 reads (5%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV100184070; called by muse, mutect2
- CGRRF1 | c.206G>C p.G69A | Missense Mutation (SNP) | VAF 46/104 reads (44%) | SIFT tolerated (0.96); PolyPhen benign (0.268); catalogued as COSV53595915, COSV53597968; called by muse, mutect2, varscan2
- CHP1 | c.466G>A p.A156T | Missense Mutation (SNP) | VAF 60/74 reads (81%) | SIFT tolerated (0.18); PolyPhen benign (0.025); catalogued as rs79101281, COSV58156679; called by muse, varscan2
- CPAMD8 | c.638A>G p.Y213C (on ENST00000651564; = p.Y166C on NM_015692.5) | Missense Mutation (SNP) | VAF 252/497 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV52232636; called by muse, mutect2, varscan2
- CSRNP3 | c.1009G>C p.D337H | Missense Mutation (SNP) | VAF 139/443 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1477194127, COSV58776434; called by muse, mutect2, varscan2
- DMBT1 | c.6098G>T p.G2033V (on ENST00000338354 / NM_001377530.1; = p.G1276V on NM_004406.3) | Missense Mutation (SNP) | VAF 133/199 reads (67%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.991); catalogued as COSV57538100; called by muse, mutect2, varscan2
- DOCK4 | c.4112C>T p.T1371I | Missense Mutation (SNP) | VAF 38/1300 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.439); catalogued as COSV101445650; called by muse, mutect2
- ENPP3 | c.1951T>C p.L651= | Splice Region (SNP) | VAF 278/909 reads (31%) | catalogued as rs775710171, COSV62953494; called by muse, mutect2, varscan2
- FAM47B | c.872G>A p.R291H | Missense Mutation (SNP) | VAF 75/149 reads (50%) | SIFT tolerated (0.2); PolyPhen benign (0.047); catalogued as rs765110360, COSV61452922; called by muse, mutect2, varscan2
- FN1 | c.6488C>G p.T2163S (on ENST00000359671 / NM_001365524.2; = p.T2132S on NM_002026.4) | Missense Mutation (SNP) | VAF 106/248 reads (43%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.997); catalogued as COSV60548809; called by muse, mutect2, varscan2
- FNTB | c.1105G>A p.G369S | Missense Mutation (SNP) | VAF 151/293 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1212071241, COSV55760527; called by muse, mutect2, varscan2
- GABRA6 | c.763G>C p.V255L | Missense Mutation (SNP) | VAF 110/261 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50878575; called by muse, mutect2, varscan2
- GRM6 | c.1717C>T p.P573S | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.04); catalogued as COSV51437063; called by muse, mutect2, varscan2
- HGH1 | c.982C>T p.R328W | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.849); catalogued as rs1427922748; called by muse, mutect2, varscan2
- KALRN | c.3425C>A p.A1142E | Missense Mutation (SNP) | VAF 294/603 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53752374, COSV53756870; called by muse, mutect2, varscan2
- KCNQ3 | c.1823C>G p.P608R | Missense Mutation (SNP) | VAF 32/125 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.066); catalogued as COSV66466454, COSV66484935; called by muse, mutect2, varscan2
- L1CAM | c.342C>G p.C114W | Missense Mutation (SNP) | VAF 32/393 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100649426; called by muse, mutect2
- LARGE2 | c.1342G>T p.A448S | Missense Mutation (SNP) | VAF 54/107 reads (50%) | SIFT tolerated (0.14); PolyPhen benign (0.043); catalogued as COSV57651394; called by muse, mutect2, varscan2
- LAS1L | c.1667A>G p.E556G | Missense Mutation (SNP) | VAF 76/178 reads (43%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV56706708; called by muse, mutect2, varscan2
- LDLRAD4 | c.662T>G p.I221S | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.079); catalogued as COSV63335132; called by muse, mutect2, varscan2
- MRRF | c.651C>G p.N217K | Missense Mutation (SNP) | VAF 135/151 reads (89%) | SIFT tolerated (0.71); PolyPhen benign (0.178); catalogued as COSV52913590; called by muse, mutect2, varscan2
- MUC16 | c.26374G>A p.G8792S | Missense Mutation (SNP) | VAF 124/1458 reads (9%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.451); catalogued as COSV67455410; called by muse, mutect2
- OR6Y1 | c.640A>C p.I214L | Missense Mutation (SNP) | VAF 143/499 reads (29%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV56928698; called by muse, mutect2, varscan2
- PCDHB9 | c.356C>G p.A119G | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated, low confidence (0.19); PolyPhen possibly damaging (0.657); catalogued as COSV53376776; called by muse, mutect2, varscan2
- PCNT | c.2564A>C p.H855P | Missense Mutation (SNP) | VAF 45/194 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.185); catalogued as COSV64026418; called by muse, mutect2, varscan2
- PDE10A | c.791T>A p.L264H | Missense Mutation (SNP) | VAF 78/93 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63093320; called by muse, mutect2, varscan2
- PDZD2 | c.6065G>A p.C2022Y | Missense Mutation (SNP) | VAF 130/498 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV56854062; called by muse, mutect2, varscan2
- PKP4 | c.2107G>A p.A703T | Missense Mutation (SNP) | VAF 87/177 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.067); catalogued as rs143377767, COSV61578597; called by muse, mutect2, varscan2
- PLEKHM2 | c.2303C>G p.P768R | Missense Mutation (SNP) | VAF 16/20 reads (80%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV65395604; called by muse, mutect2, varscan2
- PPP1R12B | c.643C>T p.R215C | Missense Mutation (SNP) | VAF 357/794 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs141513696; called by muse, mutect2, varscan2
- PRDM1 | c.1289G>A p.S430N | Missense Mutation (SNP) | VAF 40/97 reads (41%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV100958963; called by muse, mutect2, varscan2
- PRKCB | c.1156T>A p.C386S | Missense Mutation (SNP) | VAF 407/898 reads (45%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.808); catalogued as COSV57771440; called by muse, mutect2, varscan2
- PUM3 | c.1023dup p.K342Qfs*8 | Frame Shift Ins (INS) | VAF 10/82 reads (12%) | catalogued as rs749329036; called by mutect2, pindel, varscan2
- QSER1 | c.3538G>C p.G1180R (on ENST00000399302; = p.G1309R on NM_001076786.3) | Missense Mutation (SNP) | VAF 88/146 reads (60%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.641); catalogued as COSV67899885; called by muse, mutect2, varscan2
- RRAGC | c.494A>G p.Y165C | Missense Mutation (SNP) | VAF 52/102 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.063); catalogued as COSV65931332; called by muse, mutect2, varscan2
- SCAMP3 | c.14G>C p.R5T | Missense Mutation (SNP) | VAF 35/77 reads (45%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.015); catalogued as rs369270567; called by muse, mutect2, varscan2
- SEC22A | c.394C>G p.L132V | Missense Mutation (SNP) | VAF 54/121 reads (45%) | SIFT tolerated (1); PolyPhen probably damaging (0.987); catalogued as COSV59371460; called by muse, mutect2, varscan2
- SERPINA5 | c.151G>C p.D51H | Missense Mutation (SNP) | VAF 77/394 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.022); catalogued as COSV61573530, COSV61573761; called by muse, mutect2, varscan2
- SFTPD | c.1084G>A p.D362N | Missense Mutation (SNP) | VAF 21/682 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100954559; called by muse, mutect2
- SHPRH | c.2830G>T p.D944Y | Missense Mutation (SNP) | VAF 82/94 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99262597; called by muse, mutect2, varscan2
- SPTAN1 | c.5350A>C p.K1784Q | Missense Mutation (SNP) | VAF 14/162 reads (9%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.977); catalogued as rs924116830, COSV100823932; called by muse, mutect2
- STYXL2 | c.406G>A p.E136K | Missense Mutation (SNP) | VAF 13/215 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54801925; called by muse, mutect2
- SUPT16H | c.1507_1511+20del p.X503_splice | Splice Site (DEL) | VAF 158/393 reads (40%) | catalogued as COSV53523181; called by mutect2, pindel, varscan2
- TARBP1 | c.2678G>A p.W893* | Nonsense Mutation (SNP) | VAF 39/44 reads (89%) | catalogued as rs766216321, COSV50180625; called by muse, mutect2, varscan2
- TECPR1 | c.2582C>T p.T861M | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.672); catalogued as rs201404771, COSV101130697; called by muse, varscan2
- TRAF3IP2 | c.641A>C p.D214A | Missense Mutation (SNP) | VAF 137/285 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60675328; called by muse, mutect2, varscan2
- TULP1 | c.1240G>C p.G414R | Missense Mutation (SNP) | VAF 8/9 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV57692175; called by mutect2, varscan2
- UBR5 | c.7478A>T p.D2493V | Missense Mutation (SNP) | VAF 257/614 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.075); catalogued as COSV55282839; called by muse, mutect2, varscan2
- UTP20 | c.719A>T p.H240L | Missense Mutation (SNP) | VAF 50/58 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55374260; called by muse, mutect2, varscan2
- VPS50 | c.1735G>T p.G579C | Missense Mutation (SNP) | VAF 14/271 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV100005158; called by muse, mutect2
- VSTM2A | c.402C>A p.Y134* | Nonsense Mutation (SNP) | VAF 11/28 reads (39%) | catalogued as COSV56492597, COSV56492923; called by muse, mutect2, varscan2
- ZC3H12A | c.1664G>A p.S555N | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV66103994, COSV66104169, COSV66104417; called by muse, mutect2, varscan2
- ZFAND1 | c.292T>A p.C98S | Missense Mutation (SNP) | VAF 52/118 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99605502; called by muse, mutect2, varscan2
- ZNF300 | c.1424C>T p.S475F | Missense Mutation (SNP) | VAF 83/173 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.675); catalogued as COSV51032721; called by muse, mutect2, varscan2
- ANXA8L1 | c.307C>T p.H103Y | Missense Mutation (SNP) | VAF 178/433 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- DSCAML1 | c.4481_4516del p.S1494_L1505del (on ENST00000321322; = p.S1434_L1445del on NM_020693.4) | In Frame Del (DEL) | VAF 44/114 reads (39%) | called by mutect2, pindel
- EXOC3 | c.620_664del p.T207_K221del | In Frame Del (DEL) | VAF 24/244 reads (10%) | called by mutect2, pindel
- LETM1 | c.1448_1457del p.K483Rfs*16 | Frame Shift Del (DEL) | VAF 7/32 reads (22%) | called by mutect2, pindel, varscan2
- TOP2A | c.611_614del p.M204Nfs*34 | Frame Shift Del (DEL) | VAF 104/784 reads (13%) | called by pindel, varscan2
- AGTPBP1 | c.1680T>A p.L560= (on ENST00000357081 / NM_001330701.2; = p.L520= on NM_015239.2) | Silent (SNP) | VAF 45/124 reads (36%) | catalogued as COSV61269800; called by muse, mutect2, varscan2
- BBS2 | c.1257A>T p.A419= | Silent (SNP) | VAF 125/251 reads (50%) | catalogued as COSV99802733; called by muse, mutect2, varscan2
- BBX | c.2301G>T p.G767= (on ENST00000325805 / NM_001142568.3; = p.G737= on NM_020235.7) | Silent (SNP) | VAF 61/130 reads (47%) | catalogued as COSV57881172; called by muse, mutect2, varscan2
- CHST2 | c.1116G>A p.A372= | Silent (SNP) | VAF 27/38 reads (71%) | catalogued as rs770246299, COSV58885059; called by muse, mutect2, varscan2
- CSMD1 | c.4530A>G p.E1510= (on ENST00000520002; = p.E1509= on NM_033225.6) | Silent (SNP) | VAF 8/14 reads (57%) | catalogued as COSV59298513; called by muse, mutect2, varscan2
- DAGLB | c.1374C>T p.A458= | Silent (SNP) | VAF 12/26 reads (46%) | catalogued as rs752141063, COSV51703022; called by muse, mutect2, varscan2
- EFR3A | c.2346G>A p.L782= | Silent (SNP) | VAF 90/198 reads (45%) | catalogued as COSV54454681; called by muse, mutect2, varscan2
- ERCC4 | c.1371C>T p.D457= | Silent (SNP) | VAF 93/209 reads (44%) | catalogued as COSV61311176; called by muse, mutect2, varscan2
- FAXC | c.156G>C p.G52= | Silent (SNP) | VAF 9/23 reads (39%) | catalogued as COSV67601735; called by muse, mutect2, varscan2
- H2BC9 | c.183G>C p.G61= | Silent (SNP) | VAF 24/296 reads (8%) | catalogued as COSV55099554; called by muse, mutect2
- ISM1 | c.360G>T p.G120= | Silent (SNP) | VAF 8/109 reads (7%) | catalogued as COSV99340262; called by muse, mutect2
- L1CAM | c.2523C>G p.V841= | Silent (SNP) | VAF 122/265 reads (46%) | catalogued as COSV62827367, COSV62828040; called by muse, mutect2, varscan2
- LCP1 | c.339C>A p.G113= | Silent (SNP) | VAF 293/308 reads (95%) | catalogued as COSV59940081; called by muse, mutect2, varscan2
- MAP7D1 | c.906G>A p.T302= | Silent (SNP) | VAF 21/33 reads (64%) | catalogued as COSV60215538; called by muse, mutect2, varscan2
- MEP1A | c.111T>C p.F37= | Silent (SNP) | VAF 38/39 reads (97%) | catalogued as COSV57918938; called by muse, mutect2, varscan2
- NISCH | c.4035C>G p.L1345= | Silent (SNP) | VAF 19/21 reads (90%) | catalogued as COSV58733733; called by muse, mutect2, varscan2
- PDE4B | c.1251G>T p.S417= | Silent (SNP) | VAF 510/595 reads (86%) | catalogued as COSV58470059; called by muse, varscan2
- RPP38 | c.63G>T p.V21= | Silent (SNP) | VAF 54/130 reads (42%) | catalogued as COSV65381804; called by muse, mutect2, varscan2
- RPTN | c.1146A>C p.P382= | Silent (SNP) | VAF 99/3842 reads (3%) | catalogued as COSV100285692; called by muse, mutect2
- SHPRH | c.2829G>A p.Q943= | Silent (SNP) | VAF 81/92 reads (88%) | catalogued as rs1030913276, COSV99262060; called by muse, mutect2, varscan2
- SUSD5 | c.258C>T p.C86= | Silent (SNP) | VAF 118/138 reads (86%) | catalogued as COSV58876486; called by muse, mutect2, varscan2
- TICRR | c.3009A>G p.E1003= | Silent (SNP) | VAF 17/472 reads (4%) | catalogued as COSV99179361; called by muse, mutect2
- WASF4P | n.915T>G | RNA (SNP) | VAF 23/60 reads (38%) | called by muse, mutect2, varscan2
